Gene-level copy-number profile of tumor specimen ALCH-B3E4-TTP1-A from ALCHEMIST case ALCH-B3E4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.4 years (23,519 days).
Specimen ALCH-B3E4-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 38abea79-3609-48b0-bb78-99d0679e5e10.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3E4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/83f479eb-8d25-4cf3-8303-995b48d38a19

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 70; copy number 1: 10,318; copy number 2: 44,317; copy number 3: 3,433; copy number 4: 754; copy number 5: 9; copy number 6: 6; copy number 7: 1; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:72,932,974–72,934,355, 1 gene (within-gene range 0–2): AC012366.1.
- chr2:232,343,116–232,368,697, 3 genes (within-gene range 0–3): NRBF2P6, ECEL1P3, AC068134.3.
- chr3:51,541,144–51,668,667, 2 genes (within-gene range 0–1): RAD54L2, RNU6ATAC29P.
- chr3:109,293,788–109,410,084, 6 genes (within-gene range 0–2): DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12.
- chr5:134,967,907–135,011,696, 1 gene (within-gene range 0–1): CATSPER3.
- chr5:135,038,831–135,040,047, 1 gene (within-gene range 0–2): C5orf66-AS1.
- chr5:171,345,343–171,386,760, 6 genes: AC091980.1, RN7SL339P, RPSAP71, SNORA70J, RPL10P8, MIR3912.
- chr5:171,419,647–171,457,626, 2 genes: FGF18, AC093246.1.
- chr5:176,726,942–176,739,458, 1 gene: AC113391.2.
- chr5:176,810,519–176,880,898, 1 gene (within-gene range 0–1): UNC5A.
- chr7:56,340,231–56,365,270, 3 genes: RNU6-1335P, SEPTIN14P24, CICP8.
- chr7:152,445,477–152,465,549, 2 genes: CCT8L1P, LINC01003.
- chr8:22,048,995–22,082,527, 1 gene: DMTN.
- chr8:22,106,874–22,109,419, 1 gene: NUDT18.
- chr9:126,589,594–126,701,032, 3 genes: AL161908.1, LMX1B, AL161908.2.
- chr9:130,400,266–130,400,565, 1 gene (within-gene range 0–1): RN7SL665P.
- chr11:8,224,309–8,268,716, 1 gene: LMO1.
- chr11:70,646,165–70,647,562, 1 gene (within-gene range 0–1): SHANK2-AS2.
- chr12:34,208,415–34,209,675, 1 gene (within-gene range 0–2): DUX4L27.
- chr13:112,197,350–112,201,000, 1 gene: LINC01070.
- chr14:99,583,017–99,625,740, 2 genes (within-gene range 0–1): Y_RNA, AL160313.1.
- chr16:81,100,875–81,220,370, 3 genes (within-gene range 0–1): PKD1L2, RNU6-1191P, AC092718.9.
- chr16:87,892,955–87,893,735, 1 gene (within-gene range 0–1): AC133539.1.
- chr16:88,718,615–88,720,459, 1 gene (within-gene range 0–1): AC138028.4.
- chr17:2,724,411–2,749,504, 3 genes: CCDC92B, MIR1253, hsa-mir-1253.
- chr17:16,342,534–16,353,656, 1 gene (within-gene range 0–1): CENPV.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–2): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr19:361,747–376,026, 1 gene: THEG.
- chr22:19,171,395–19,178,739, 2 genes: LINC01311, SLC25A1.
- chr22:30,598,309–30,627,271, 2 genes (within-gene range 0–2): AC005006.1, TCN2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:36,784,324–37,095,390, 6 genes, copy number 6: KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4.
- chr8:143,915,153–143,976,734, 2 genes, copy number 5: PLEC, MIR661.
- chr9:136,744,017–136,748,525, 2 genes, copy number 9 (within-gene range 3–9): LCN6, MIR6722.
- chr19:1,000,419–1,021,179, 3 genes, copy number 5–7 (within-gene range 1–7): GRIN3B, TMEM259, AC004528.2.
- chr19:1,065,923–1,086,628, 1 gene, copy number 5 (within-gene range 4–5): ARHGAP45.
- chr20:62,774,121–62,814,000, 4 genes, copy number 5: LINC00659, MRGBP, OGFR-AS1, OGFR.

Autosomal genes at a single copy (total copy number 1): 7,537. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
